Gene-level copy-number profile of tumor specimen TCGA-BD-A3ER-01A from TCGA case TCGA-BD-A3ER, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 62.0 years (22,657 days).
Specimen TCGA-BD-A3ER-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.cb528209-57ce-4b5a-9001-95a5afe8e9f8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BD-A3ER-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2c4cebe7-66d3-4512-8384-82156ec2f229

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,489; copy number 2: 51,457; copy number 3: 3,573; copy number 4: 1,285; copy number 5: 9; copy number 6: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-BD-A3ER-01): tumor purity 0.55, ploidy 2.1, whole-genome doublings 0 (call status: maf_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 15 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:180,573,464–180,759,038, 2 genes, copy number 5: NDUFB5P1, AC104803.1.
- chr8:59,455,885–59,821,433, 6 genes, copy number 6: RNA5SP267, AC087664.3, AC087664.1, AC087664.2, AC107934.1, AC107934.2.
- chr8:126,556,323–127,419,050, 1 gene, copy number 5 (within-gene range 3–5): PCAT1.
- chr8:127,072,694–127,257,630, 4 genes, copy number 5: CASC19, PRNCR1, AC020688.1, AC018714.2.
- chr8:127,292,233–127,420,066, 2 genes, copy number 5 (within-gene range 3–5): AC018714.1, POU5F1B.

Autosomal genes at a single copy (total copy number 1): 1,113. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
